Somatic mutation profile of tumor specimen TCGA-D1-A0ZQ-01A (aliquot TCGA-D1-A0ZQ-01A-11D-A122-09) from TCGA case TCGA-D1-A0ZQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-D1-A0ZQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ce22c71-6ec4-42a3-b871-35d78acc15ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZQ-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZQ-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/230e87d2-76d0-4bd1-bca6-ab94e598417e

The open-access MAF lists 89 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 21, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 3, RNA 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 61/141 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.188del p.N63Tfs*36 | Frame Shift Del (DEL) | VAF 198/307 reads (64%) | catalogued as rs1554897267, COSV64298134; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC023055.1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV60243166, COSV60244058; called by muse, mutect2, varscan2
- ALOXE3 | c.1771G>C p.V591L | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV59074130; called by muse, mutect2, varscan2
- AMACR | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs776423865, COSV59460773; called by muse, mutect2, varscan2
- ARMC5 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51656067; called by muse, mutect2, varscan2
- ATXN7L2 | c.895A>C p.S299R | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV63992262; called by muse, mutect2, varscan2
- CBR1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs146559297; called by muse, mutect2, varscan2
- CELSR2 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759400632, COSV54770794; called by muse, mutect2, varscan2
- CNTFR | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774551895, COSV63633668; called by muse, mutect2, varscan2
- COL24A1 | c.3931C>A p.P1311T | Missense Mutation (SNP) | VAF 125/301 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV65305565; called by muse, mutect2, varscan2
- COL26A1 | c.752G>A p.R251H (on ENST00000313669 / NM_001278563.3; = p.R249H on NM_133457.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.083); catalogued as rs372045140; called by muse, mutect2, varscan2
- DCBLD1 | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 113/198 reads (57%) | catalogued as COSV51640496; called by muse, mutect2, varscan2
- DCC | c.3620G>T p.G1207V | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1439819758, COSV71431502; called by muse, mutect2, varscan2
- F2RL2 | c.1052G>C p.S351T | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs779249772, COSV56970561; called by muse, mutect2, varscan2
- FAT1 | c.10067C>T p.T3356M | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); catalogued as rs760734038, COSV71671884; called by muse, mutect2, varscan2
- FZD6 | c.938G>T p.R313I | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.781); catalogued as COSV62471283; called by muse, mutect2, varscan2
- GAPT | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148170353, COSV59246909; called by muse, mutect2, varscan2
- GON4L | c.6696C>A p.D2232E | Missense Mutation (SNP) | VAF 13/415 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.622); catalogued as COSV55192878; called by muse, mutect2
- GPC5 | c.1492T>G p.C498G | Missense Mutation (SNP) | VAF 135/398 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65595299; called by muse, mutect2, varscan2
- GPR143 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV66632334, COSV66632361; called by muse, mutect2, varscan2
- GRIN2A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs560057284, COSV58020945, COSV58030818; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ITPR2 | c.4643G>T p.G1548V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV67268698, COSV67275745; called by muse, mutect2, varscan2
- MAP1B | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57098220; called by muse, mutect2
- MBD3L2 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV61588929; called by muse, mutect2, varscan2
- MED12 | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 132/330 reads (40%) | catalogued as COSV61338670; called by muse, mutect2, varscan2
- MON2 | c.2754-2A>T p.X918_splice | Splice Site (SNP) | VAF 96/260 reads (37%) | catalogued as rs754113679, COSV54806588; called by muse, mutect2, varscan2
- MTCL1 | c.1324G>T p.V442L (on ENST00000306329 / NM_001378206.1; = p.V82L on NM_015210.4) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV60405688; called by muse, mutect2, varscan2
- MYCBP2 | c.5741T>C p.I1914T (on ENST00000357337; = p.I1952T on NM_015057.5) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs1160348831, COSV62017253; called by muse, mutect2, varscan2
- NELL1 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV54260399, COSV54334467; called by muse, mutect2
- NPAS2 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs769103203, COSV59557397, COSV59563156; called by muse, mutect2, varscan2
- NT5E | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs377417331; called by muse, mutect2, varscan2
- NTHL1 | c.675_681del p.M226Wfs*22 (on ENST00000219066; = p.M218Wfs*22 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as COSV54592872; called by mutect2, pindel, varscan2
- OR10A7 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs780749697, COSV58278268; called by muse, mutect2, varscan2
- OR1E2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 16/408 reads (4%) | catalogued as COSV50265584; called by muse, mutect2
- OR5AS1 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57981644; called by muse, varscan2
- PACSIN1 | c.520del p.E174Rfs*2 | Frame Shift Del (DEL) | VAF 51/181 reads (28%) | catalogued as COSV99763036, COSV99763148; called by mutect2, pindel, varscan2
- PCDHA8 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); catalogued as rs782356855, COSV65326001; called by muse, mutect2, varscan2
- PCDHA8 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); catalogued as rs782524668, COSV65326007, COSV65329018; called by muse, mutect2, varscan2
- PIAS4 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.321); catalogued as rs769605924, COSV53678977; called by muse, mutect2, varscan2
- POU3F4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs1387725375, COSV64538791, COSV64540956; called by muse, mutect2, varscan2
- PRPF8 | c.5625_5627del p.H1875_L1876delinsQ | In Frame Del (DEL) | VAF 78/209 reads (37%) | catalogued as COSV59263070; called by mutect2, pindel, varscan2
- PTPRB | c.5687G>A p.G1896D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV54239507; called by muse, mutect2, varscan2
- RBSN | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs370942309, COSV99515563; called by muse, mutect2, varscan2
- RNF25 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV55307086; called by muse, mutect2
- RYR2 | c.8504G>A p.R2835K | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.665); catalogued as COSV63682693; called by muse, mutect2, varscan2
- SCN9A | c.5608G>T p.A1870S (on ENST00000303354; = p.A1859S on NM_002977.3) | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV57600950, COSV57608157; called by muse, mutect2, varscan2
- SERINC3 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54856575; called by muse, mutect2, varscan2
- SLITRK2 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs1556943747, COSV59425029; called by muse, mutect2, varscan2
- SLX4 | c.4750C>T p.R1584C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560866356, COSV53563636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.3444G>T p.R1148S | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV63809073; called by muse, mutect2, varscan2
- SPOP | c.845T>G p.L282R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61653836; called by muse, mutect2, varscan2
- SPOP | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 69/184 reads (38%) | catalogued as COSV61653841; called by muse, mutect2, varscan2
- SPTA1 | c.2474T>G p.L825R | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63752386; called by muse, mutect2, varscan2
- TECTA | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.091); catalogued as COSV50704149; called by muse, mutect2, varscan2
- TNS1 | c.3155C>A p.T1052N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV50700860; called by muse, mutect2, varscan2
- TTN | c.102196C>A p.Q34066K (on ENST00000591111; = p.Q26642K on NM_003319.4) | Missense Mutation (SNP) | VAF 92/243 reads (38%) | PolyPhen possibly damaging (0.543); catalogued as COSV60021890; called by muse, mutect2, varscan2
- VIT | c.1631G>A p.R544Q (on ENST00000389975 / NM_001177969.1; = p.R559Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368730658; called by muse, mutect2, varscan2
- VPS45 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.184); catalogued as rs200783288, COSV64887631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF174 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51902571; called by muse, mutect2, varscan2
- ZNF449 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV59346913; called by muse, mutect2, varscan2
- PIK3R1 | c.1351_1354delinsC p.E451_Y452delinsH (on ENST00000521381 / NM_181523.3; = p.E181_Y182delinsH on NM_181504.4) | In Frame Del (DEL) | VAF 50/152 reads (33%) | called by pindel, varscan2*
- PIK3R1 | c.1759_1761del p.K587del (on ENST00000521381 / NM_181523.3; = p.K317del on NM_181504.4) | In Frame Del (DEL) | VAF 167/487 reads (34%) | called by mutect2, pindel, varscan2
- ZNF607 | c.1231_1241delinsAATACA p.H411Nfs*6 | Frame Shift Del (DEL) | VAF 44/192 reads (23%) | called by pindel, varscan2*
- AP4B1 | c.1644G>A p.P548= | Silent (SNP) | VAF 62/177 reads (35%) | catalogued as rs376974229, COSV56724633; called by muse, mutect2, varscan2
- B3GALT2 | c.903C>T p.D301= | Silent (SNP) | VAF 84/374 reads (22%) | catalogued as rs753926771, COSV66464009; called by muse, mutect2, varscan2
- CDX4 | c.372C>T p.S124= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV65171442; called by muse, mutect2
- CYFIP2 | c.924C>T p.F308= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as rs539257822, COSV59029656; called by muse, mutect2, varscan2
- DLGAP1 | c.387G>A p.E129= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1287588880, COSV59800788; called by muse, mutect2, varscan2
- DNAH1 | c.5289G>A p.S1763= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as rs376275863; ClinVar: likely benign; called by muse, mutect2, varscan2
- E2F8 | c.1503C>T p.P501= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as COSV51463199; called by muse, mutect2, varscan2
- EBF3 | c.948G>C p.P316= (on ENST00000355311 / NM_001375392.1; = p.P307= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/243 reads (25%) | catalogued as COSV62474601; called by muse, mutect2, varscan2
- EME1 | c.1236G>A p.L412= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV56814380; called by muse, mutect2, varscan2
- EPN1 | c.219C>T p.H73= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs777886395, COSV50037284; called by muse, mutect2, varscan2
- KIAA1217 | c.1389G>A p.L463= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV56816004; called by muse, mutect2, varscan2
- MAP3K8 | c.168C>T p.N56= | Silent (SNP) | VAF 102/205 reads (50%) | catalogued as rs780414317, COSV53919600; called by muse, mutect2, varscan2
- NPBWR1 | c.246C>T p.A82= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs759280388, COSV58696097; called by muse, mutect2, varscan2
- PDE10A | c.357C>T p.A119= | Silent (SNP) | VAF 155/273 reads (57%) | catalogued as rs778126794, COSV63095722; ClinVar: likely benign; called by muse, mutect2, varscan2
- PI4KB | c.1893C>G p.L631= (on ENST00000368873 / NM_001369623.1; = p.L643= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV55016300, COSV55017063; called by muse, mutect2, varscan2
- PITPNM3 | c.1830A>G p.A610= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV52595278; called by muse, mutect2, varscan2
- PPIL2 | c.1056C>T p.D352= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs751394220, COSV58606243; called by muse, mutect2, varscan2
- RPS6KB2 | c.1002C>T p.D334= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as rs55850698; called by muse, mutect2, varscan2
- SHCBP1L | c.693G>A p.V231= | Silent (SNP) | VAF 143/279 reads (51%) | catalogued as COSV62354711; called by muse, mutect2, varscan2
- TMEM132B | c.459G>A p.T153= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs757343384, COSV54744468, COSV54771471; called by muse, mutect2, varscan2
- VENTX | c.495G>A p.A165= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs540901758, COSV58084363; called by muse, mutect2, varscan2
- MIR543 | n.3C>T | RNA (SNP) | VAF 158/396 reads (40%) | called by muse, mutect2, varscan2
- OR52A4P | n.996C>T | RNA (SNP) | VAF 29/67 reads (43%) | catalogued as rs61880361; called by muse, mutect2, varscan2
- SSH1 | c.111-13644G>A | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs776912951, COSV58464518; called by muse, mutect2, varscan2
